Gene-level copy-number profile of tumor specimen HCM-CSHL-0160-C18-01B from HCMI case HCM-CSHL-0160-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: GB; Age at diagnosis: 83.9 years (30,635 days).
Specimen HCM-CSHL-0160-C18-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6f8483de-a057-431b-83d6-f5eb5e5fb792.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0160-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/2dd94b46-88d7-4dbf-81a1-25809abb2e3a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 8,239; copy number 2: 41,392; copy number 3: 6,612; copy number 4: 1,412; copy number 5: 733; copy number 15: 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:73,376,399–73,397,474, 2 genes: RELT, AP000763.4.
- chr12:109,880,676–109,888,467, 1 gene: AC007834.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 734 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:242,175,181–242,175,634, 1 gene, copy number 15: RPL23AP88.
- chr12:120,740,470–120,761,592, 1 gene, copy number 5: AC069234.1.
- chr20:30,214,765–61,940,617, 732 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,239. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
